CPTAC case C3L-03510 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6f635a5d-8f03-4d80-9371-9afb16262eb8

Demographics
Sex at birth: male; Race: white; Year of birth: 1969; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Age at diagnosis: 51.8 years (18,904 days); Year of diagnosis: 2020; Days to last known disease status: 1,464 days (4.0 years); Progression or recurrence: yes; Days to recurrence: 1,287 days (3.5 years); Days to last follow up: 1,464 days (4.0 years).
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Immunotherapy (Including Vaccines) — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Stem Cell Transplantation, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 248 days; ECOG performance status: 0.
- Days to follow up: 652 days (1.8 years); ECOG performance status: 0.

Other clinical attributes
- Weight: 80 kg; Height: 170 cm; BMI: 27.68.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 10.5; Cigarettes per day: 10; Tobacco smoking onset year: 1999; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 23.

Biospecimens (3 samples)
- Sample C3L-03510-50: Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Sample C3L-03510-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Time between excision and freezing: 350 minutes.
- Sample C3L-03510-55: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 0 days; Time between excision and freezing: 350 minutes; Method of sample procurement: Bone Marrow Aspirate; Diagnosis pathologically confirmed: Yes.
